Somatic mutation profile of tumor specimen TARGET-50-PAJMSE-01A (aliquot TARGET-50-PAJMSE-01A-01D) from TARGET case TARGET-50-PAJMSE, project TARGET-WT (High-Risk Wilms Tumor). Sex at birth: female; Vital status: Dead; Primary diagnosis: Wilms tumor; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 4.6 years (1,681 days).
Specimen TARGET-50-PAJMSE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c1b10803-e573-417f-baae-cd9da53a6c27.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-50-PAJMSE-10A (Blood Derived Normal), aliquot TARGET-50-PAJMSE-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/792621c7-d9d4-44f5-a9cb-12f5e7e63969

The open-access MAF lists 5 somatic variants for this specimen: 5 protein-altering or splice-affecting.
By variant classification: Missense Mutation 5.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DROSHA | c.3439G>A p.E1147K | Missense Mutation (SNP) | VAF 166/373 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60772213; called by muse, mutect2, varscan2
- ADGRV1 | c.14576G>T p.G4859V | Missense Mutation (SNP) | VAF 202/510 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.328); called by muse, varscan2
- PLXNA4 | c.4368G>T p.E1456D | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SYNC | c.1003A>G p.S335G | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.965); called by muse, mutect2
- TNS3 | c.2392G>A p.A798T | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated (0.75); PolyPhen benign (0.001); called by muse, mutect2
